Somatic mutation profile of tumor specimen ALCH-B1KY-TTP1-A (aliquot ALCH-B1KY-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1KY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.5 years (26,098 days).
Specimen ALCH-B1KY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d20bf15c-6a12-4ec6-a0dd-5672f8b38d8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1KY-NB1-A (Blood Derived Normal), aliquot ALCH-B1KY-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a797fc3-b55f-4d6a-92ef-6843d2b5f004

The open-access MAF lists 54 somatic variants for this specimen: 36 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 14, Nonsense Mutation 4, Intron 3, Frame Shift Del 2, In Frame Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 203/750 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3019G>C p.G1007R | Missense Mutation (SNP) | VAF 5/68 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.797); catalogued as COSV55882140; called by muse, mutect2
- ABTB1 | c.1324G>A p.D442N (on ENST00000232744 / NM_172027.3; = p.D300N on NM_032548.3) | Missense Mutation (SNP) | VAF 26/435 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV51739973; called by muse, mutect2
- CLEC4E | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs768306307, COSV55226802; called by muse, varscan2
- GXYLT2 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 17/123 reads (14%) | catalogued as rs536663438, COSV67475075; called by muse, mutect2, varscan2
- OR2H2 | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 34/371 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs766577192; called by muse, mutect2
- PI16 | c.1205C>G p.P402R | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.271); catalogued as COSV101010238; called by muse, mutect2
- RNF111 | c.407A>G p.D136G | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as rs1432027198, COSV100789033; called by muse, mutect2
- RNF32 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.439); catalogued as rs199618037; called by muse, mutect2, varscan2
- SPAST | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878854991, CM052368; ClinVar: pathogenic / conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- SYTL2 | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); catalogued as COSV104412915; called by muse, mutect2, varscan2
- TM7SF3 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1318715501; called by muse, mutect2, varscan2
- TRARG1 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61562723; called by muse, mutect2
- ADGB | c.2677T>C p.Y893H | Missense Mutation (SNP) | VAF 17/309 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.378); called by muse, mutect2
- ALG10B | c.484T>C p.F162L | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.023); called by muse, mutect2
- ATP2B2 | c.2127C>A p.C709* (on ENST00000352432; = p.C675* on NM_001683.5) | Nonsense Mutation (SNP) | VAF 27/160 reads (17%) | called by muse, mutect2, varscan2
- ATP2C1 | c.29C>G p.P10R | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.157); called by muse, varscan2
- CHD9 | c.3409A>G p.M1137V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CHTF18 | c.2434C>T p.Q812* | Nonsense Mutation (SNP) | VAF 45/365 reads (12%) | called by muse, mutect2, varscan2
- EDDM3A | c.18_19del p.K6Nfs*20 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- GABRD | c.1341G>A p.W447* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- H3C7 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 19/378 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); called by muse, mutect2
- ICAM1 | c.1146A>G p.I382M | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ITGAX | c.1040T>C p.F347S | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K5 | c.2445T>A p.S815R | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MTMR8 | c.749A>G p.N250S | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKN3 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHA1 | c.810+1G>T p.X270_splice | Splice Site (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- PROKR1 | c.161A>C p.N54T | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- SFT2D3 | c.317_328del p.R106_A109del | In Frame Del (DEL) | VAF 62/476 reads (13%) | called by mutect2, pindel
- SRSF6 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- TEKT3 | c.1283A>G p.D428G | Missense Mutation (SNP) | VAF 23/414 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); called by muse, mutect2
- TMEM68 | c.946A>G p.M316V (on ENST00000434581 / NM_001363177.1; = p.M249V on NM_152417.3) | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTI2 | c.1478del p.I493Tfs*40 | Frame Shift Del (DEL) | VAF 65/332 reads (20%) | called by mutect2, pindel, varscan2
- ZFHX2 | c.2106C>A p.D702E | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ZNF461 | c.420T>G p.I140M | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ABCA1 | c.6720A>T p.T2240= | Silent (SNP) | VAF 34/256 reads (13%) | called by muse, mutect2, varscan2
- CBY3 | c.630G>A p.P210= | Silent (SNP) | VAF 94/251 reads (37%) | catalogued as rs927808035; called by muse, mutect2, varscan2
- CTPS1 | c.63C>T p.S21= | Silent (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2, varscan2
- DSG3 | c.1803C>T p.T601= | Silent (SNP) | VAF 63/582 reads (11%) | called by muse, mutect2, varscan2
- ENO1 | c.681G>T p.L227= | Silent (SNP) | VAF 63/403 reads (16%) | called by muse, mutect2, varscan2
- FCGBP | c.6825G>A p.P2275= | Silent (SNP) | VAF 65/1038 reads (6%) | catalogued as rs1465074897; called by muse, mutect2
- PTH1R | c.729G>A p.V243= | Silent (SNP) | VAF 36/219 reads (16%) | called by muse, mutect2, varscan2
- SCAF1 | c.3651G>A p.A1217= | Silent (SNP) | VAF 45/244 reads (18%) | catalogued as rs764369819, COSV59193052; called by muse, mutect2, varscan2
- SLC13A1 | c.768C>A p.I256= | Silent (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- TAS2R9 | c.360C>T p.F120= | Silent (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- TNPO3 | c.1216C>T p.L406= | Silent (SNP) | VAF 27/181 reads (15%) | called by muse, mutect2, varscan2
- TXNDC11 | c.411T>C p.C137= | Silent (SNP) | VAF 20/560 reads (4%) | called by muse, mutect2
- TXNIP | c.732A>T p.S244= | Silent (SNP) | VAF 73/541 reads (13%) | called by muse, mutect2, varscan2
- ZNF793 | c.324G>A p.L108= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- ACOT8 | c.841+182G>A | Intron (SNP) | VAF 27/305 reads (9%) | called by muse, mutect2
- C10orf143 | c.69+2983C>G | Intron (SNP) | VAF 29/225 reads (13%) | called by muse, mutect2, varscan2
- DEK | c.-123C>T | 5'UTR (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2
- GDAP1L1 | c.374-169G>C | Intron (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
